Surgical pathology report (de-identified scan), TCGA case TCGA-AF-A56N, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-A56N-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma, NOS
8140/3
Site: Colon, rectosigmoid
C19.9
12/17/12 gjd

Final Surgical Pathology Report

Diagnosis

A. Uterus, bilateral ovaries and fallopian tubes, supracervical hysterectomy:
Endometrium: Benign inactive endometrium
Myometrium: Benign leiomyomata
Serosa: No pathological abnormalities
Bilateral ovaries: Benign with cystic follicles and minimal surface adhesions
Bilateral fallopian tubes: Benign with no pathologic abnormalities

B. Rectum and sigmoid colon, excision:
Adenocarcinoma, moderately differentiated, invasive into perirectal/colonic fat (pT3)
Resection margins negative for malignancy
33 lymph nodes negative for malignancy (0/33) (pN0)

C. Appendix, excision:
Benign appendix with mucosal lymphoid hyperplasia, within normal limits

Microscopic Description:

Microscopic examination performed. The colorectal findings from specimen B. are summarized in the template:
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): Invasive into fat (pT3)
Proximal margin: Negative
Distal margins: Negative
Circumferential (radial) margin: Negative
Distance of tumor from closest margin: 1.9 CM from distal/rectal margin
Vascular invasion: Not identified
Regional lymph nodes (pN): 33 lymph nodes are negative for metastatic tumor (pN0)
Non-lymph node pericolic tumor: Not identified
Distant metastasis (pM): Not applicable (pMx)
Other findings: There is surface ulceration of tumor and some associated acute and chronic inflammation of the tumor with Crohn's-like chronic inflammation deep to the tumor. The invasion into fat is only identified in block B3
MSI testing: Ordered on block B2

Specimen

A. Uterus tubes and ovaries
B. Rectum and sigmoid
C. Appendix

Clinical Information
Rectal cancer

Intraoperative Consultation

A. Uterus, tubes and ovaries: Benign inactive endometrium.
B. Rectum & sigmoid, excision: Negative for tumor.

[page 2 of 2]
Gross Description

A. Received fresh and subsequently fixed in formalin labeled "uterus tubes and ovaries" is a 294 g, supracervically amputated uterus which is 7.5 x 7.5 x 7.5 cm. The specimen is partially covered pink-tan smooth glistening serosa showing 3 subserosal fibroid ranging from 1.3 cm to 4.5 cm in greatest dimension. Amputation site is inked. The specimen has attached bilateral fallopian tubes which are both fimbriated measuring 8.0 x 0.7 cm. The ovaries are also present averaging 3.2 x 1.7 x 1.4 cm and are pink-tan and cerebriform with a pink-tan cystic and mottled cut surface. No papillary excrescences are grossly identified. The specimen is opened show smooth glistening endometrium with an average thickness of 0.2 cm. The specimen is sectioned to show multiple intramural fibroids which range from 0.1 cm to 5.5 cm in greatest dimension. Due to the nodular distortion of the specimen, average thickness of the myometrium cannot be grossly determined. Possible cystic spaces may be grossly identified subjacent to the endometrium a 1.2 cm area. This is located within 2.8 cm of the amputation site. Representative sections of the specimen are submitted as follows: AFS 1 representative section of endometrium and myometrium , 1 - representative section of amputation site 2 - 3 - representative endomyometrium with subjacent fibroid and area of cystic spaces, 4 - are present at section of 2 smaller subserosal fibroids, 5 - representative section of large subserosal fibroid, 6 - 8 - representative section of largest intramural fibroid, 9 - representative right ovary, 10 - representative left ovary, 11 - representative right fallopian tube with entire fimbria, 12 - representative left fallopian tube with entire fimbria. RS 12

B. Received fresh and subsequently fixed in formalin labeled "rectum and sigmoid" is a 26.5 cm long portion of rectosigmoid colon which is partially covered with abundant yellow lobular fat and pink-tan smooth glistening serosa. Retroperitoneal reflection is located 8.5 cm from the distal end which is inked black. The specimen is opened to show a 5.5 x 4.8 x 0.8 cm exophytic tumor coming within 1.9 cm of distal margin. The cut surface of the tumor shows invasion into the muscularis propria but shows no discrete invasion into the fat. This comes within 2.5 cm or greater of the radial margin. The remainder of the mucosa is pink-tan smooth glistening with an average circumference of 5.5 cm showing no other discrete gross lesions identified. Multiple lymph nodes are grossly identified in the surrounding fat. Representative sections of the specimen are submitted as follows: BFS 1 representative radial section of distal margin 1 - representative luminal margins, 2 - tumor to distal margin, 3 - 5 - additional representative sections of tumor to fat and tumor to normal, 6 - representative section of radial margin en face, 7 - 13 - 5 possible lymph nodes in each block, 14 - 2 possible lymph nodes, 15 - 1 possible lymph node bisected. RS 15.

C. Received in formalin labeled "appendix" is a 7.9 x 0.7 x 0.7 cm grossly unremarkable appendix. The specimen is sectioned to show an intact wall with no discrete gross lesions identified. Representative sections of the specimen are submitted in 2 cassettes with the proximal end inked blue. RS 2.

Site AA Discrepancy		
Site Malignancy History		
Core is Identical		
Review of Histology		

Source: NCI Genomic Data Commons file ad704aaf-1e09-4b6e-9989-aeec1e5705e6 (TCGA-AF-A56N.858B2578-437F-466E-8FAD-7E755DD4B322.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).